Gene-level copy-number profile of tumor specimen TCGA-13-0791-01A from TCGA case TCGA-13-0791, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.5 years (21,380 days).
Specimen TCGA-13-0791-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.cfb6aa16-69ca-422f-b5c3-cf546d4964f5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0791-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 833 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/defe5a2d-bab9-4d25-aab9-2d3f9780423d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,423; copy number 3: 4,735; copy number 4: 31,672; copy number 5: 4,426; copy number 6: 7,615; copy number 7: 1,061; copy number 8: 1,148; copy number 9: 698; copy number 10: 147; copy number 11: 472; copy number 12: 145; copy number 13: 101; copy number 14: 51; copy number 15: 17; copy number 16: 17; copy number 17: 10; copy number 18: 2; copy number 19: 40; copy number 22: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0791-01A-01D-0356-01): tumor purity 0.89, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,685 genes in 55 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,713,877–38,214,806, 81 genes, copy number 11 (broad region; genes not listed).
- chr1:46,134,531–46,316,776, 8 genes, copy number 12: AL358075.2, TSPAN1, P3R3URF, POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH.
- chr1:76,867,480–78,171,237, 34 genes, copy number 9: ST6GALNAC5, MIR7156, AL035409.2, AL035409.1, PIGK, AC113935.1, AC093433.1, AC093433.2, AK5, AC095030.1, RNU7-8P, AC093575.1, ZZZ3, RNA5SP20, RN7SL370P, USP33, ACTG1P21, MIGA1, RNA5SP21, AC138392.1, NSRP1P1, HSPE1P25, NEXN-AS1, NEXN, FUBP1, DNAJB4, GIPC2, AC103591.3, AC103591.4, AC103591.2, RNU6-1102P, AC103591.1, RNA5SP22, RNFT1P2.
- chr1:149,832,659–151,459,494, 94 genes, copy number 9 (broad region; genes not listed).
- chr1:205,566,716–205,943,460, 16 genes, copy number 11: RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, AC119673.1, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1.
- chr2:126,898,864–129,273,848, 54 genes, copy number 9: TEX51, RNU7-182P, AC012508.2, AC012508.3, AC012508.1, BIN1, AC110926.1, NIFKP9, CYP27C1, WBP11P2, ERCC3, AC068282.1, MAP3K2, RNU6-1147P, MAP3K2-DT, AC068282.2, PROC, MIR4783, IWS1, AC010976.1, RNU4-48P, MYO7B, AC010976.2, LIMS2, GPR17, WDR33, SFT2D3, RNY4P7, Y_RNA, ZFP91P1, POLR2D, RNU6-395P, RPS26P19, Metazoa_SRP, AMMECR1L, AC012306.2, AC012306.3, AC012306.1, SAP130, AC108059.2, Y_RNA, UGGT1, SRMP3, AC108059.1, DYNLT3P2, RPL14P6, RPL21P34, HS6ST1, Y_RNA, RNA5SP103, ISCA1P6, AC012451.1, AC068483.1, LINC01854.
- chr3:52,075,226–52,809,009, 43 genes, copy number 9 (within-gene range 6–9): POC1A, AC097637.3, ALDOAP1, ALAS1, AC097637.2, TLR9, AC097637.1, TWF2, AC006252.1, PPM1M, WDR82, MIRLET7G, GLYCTK, GLYCTK-AS1, MIR135A1, DNAH1, PPP2R5CP, BAP1, PHF7, SEMA3G, TNNC1, NISCH, STAB1, NT5DC2, SMIM4, PBRM1, RNU6-856P, RNU6ATAC16P, GNL3, AC104446.3, AC104446.1, SNORD19, SNORD19B, SNORD19C, SNORD69, GLT8D1, SPCS1, NEK4, AC104446.2, AC006254.2, AC006254.3, ITIH1, ITIH3.
- chr3:54,874,605–57,170,306, 24 genes, copy number 10: CACNA2D3-AS1, LRTM1, AC092059.1, LINC02017, LINC02030, AC121764.2, AC121764.3, WNT5A, WNT5A-AS1, AC121764.1, ERC2, AC025572.1, ERC2-IT1, MIR3938, RN7SKP45, RNA5SP133, CCDC66, TASOR, ARHGEF3, ARHGEF3-AS1, SPATA12, AC097358.2, IL17RD, AC097358.1.
- chr3:137,998,735–139,782,699, 46 genes, copy number 9–12 (within-gene range 4–12): CLDN18, AC016252.1, DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A, MRPS22, PRR23B, PRR23C, RPL7L1P7, BPESC1, PISRT1, AC119740.1, AC024933.2, AC024933.1, COPB2, U6, AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P, AC110716.2, AC110716.1.
- chr3:148,791,102–152,679,450, 97 genes, copy number 11–17 (broad region; genes not listed).
- chr3:166,160,021–174,286,644, 127 genes, copy number 9–22 (broad region; genes not listed).
- chr4:56,467,617–56,821,742, 13 genes, copy number 9 (within-gene range 6–9): SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA.
- chr4:73,259,209–73,544,013, 8 genes, copy number 9: AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1.
- chr4:168,755,816–170,372,311, 28 genes, copy number 13: RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512.
- chr4:175,574,868–177,691,068, 25 genes, copy number 9–11: ADAM20P2, GPM6A, AC097537.1, AC110794.1, MARK2P4, WDR17, AC093605.1, SPATA4, ASB5, SPCS3-AS1, SPCS3, AC093801.2, AC093801.1, VEGFC, AC097518.2, AC092673.1, LINC02509, RN7SKP136, AC097518.1, NEIL3, AC027627.1, AGA, AC078881.1, RNA5SP172, AC103879.1.
- chr5:34,105,750–39,274,528, 92 genes, copy number 9–13 (broad region; genes not listed).
- chr5:73,454,187–75,512,138, 41 genes, copy number 10 (within-gene range 4–10): LINC01386, AC099522.2, BTF3, FUNDC2P1, ANKRA2, UTP15, ARHGEF28, AC091868.2, AC091868.1, RNU7-196P, AC093283.1, LINC02122, LINC01331, LINC01335, RN7SL814P, LINC01333, LINC01332, ENC1, HEXB, GFM2, RNU6-658P, NSA2, FAM169A, RNU6-1330P, AC093214.1, AC010501.2, AC010501.1, AC116337.4, AC116337.3, AC116337.1, AC116337.2, RPL27AP5, AC093259.1, GCNT4, ANKRD31, SUMO2P5, AC008897.2, HMGCR, CERT1, AC008897.3, AC008897.1.
- chr6:26,251,651–27,407,996, 50 genes, copy number 9: H2BC9, H3C8, H2AC10P, H2BC10, H4C8, H3C9P, AL021917.1, BTN3A2, BTN2A2, BTN3A1, BTN2A3P, BTN3A3, BTN2A1, BTN1A1P1, BTN1A1, RNU6-502P, HCG11, HMGN4, AL121936.1, ABT1, AL513548.3, AL513548.2, ZNF322, AL513548.4, AL513548.1, GUSBP2, POM121L6P, LINC00240, AL133255.1, AL590062.1, VN1R12P, VN1R13P, VN1R11P, RNU2-62P, AL021807.1, H2BC11, H2AC11, H4C9, H2BC12, H2AC12, MIR3143, RPL10P2, PRSS16, AL021808.1, POM121L2, VN1R10P, ZNF204P, ZNF391, AL031118.1, MCFD2P1.
- chr7:20,217,577–23,832,513, 64 genes, copy number 9–19 (within-gene range 6–19) (broad region; genes not listed).
- chr7:77,122,434–77,995,171, 14 genes, copy number 13 (within-gene range 8–13): CCDC146, FGL2, AC098851.1, GSAP, AC004921.1, GCNT1P5, AC004921.2, PTPN12, APTR, RSBN1L, TMEM60, PHTF2, Y_RNA, AC004990.1.
- chr7:80,096,600–81,432,796, 15 genes, copy number 9: RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2.
- chr8:79,520,145–79,871,759, 8 genes, copy number 9 (within-gene range 6–9): AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P.
- chr8:123,041,968–124,462,150, 43 genes, copy number 11: TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12.
- chr8:129,685,401–130,443,674, 18 genes, copy number 10: AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1.
- chr9:15,776,181–17,114,122, 9 genes, copy number 10 (within-gene range 6–10): RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1.
- chr10:62,682,652–64,693,446, 23 genes, copy number 9–14: AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35.
- chr10:97,319,271–97,433,444, 8 genes, copy number 9: FRAT1, FRAT2, AL355490.1, RRP12, RPL34P20, AL355490.2, Y_RNA, PGAM1.
- chr11:101,451,564–105,531,697, 76 genes, copy number 9–14 (within-gene range 8–14) (broad region; genes not listed).
- chr11:128,880,325–133,532,519, 61 genes, copy number 11–18 (within-gene range 6–18) (broad region; genes not listed).
- chr12:21,662,313–21,942,529, 6 genes, copy number 9 (within-gene range 6–9): AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2.
- chr12:55,608,043–55,662,501, 6 genes, copy number 9 (within-gene range 6–9): OR6U2P, OR10P1, AC009779.4, OR10AE3P, PSMB3P1, AC009779.5.
- chr13:51,584,455–54,986,720, 58 genes, copy number 9: WDFY2, RNY1P6, RN7SL413P, ATP5PBP1, AL162377.3, DHRS12, AL162377.1, TMEM272, CCDC70, CTAGE3P, AL162377.2, ATP7B, FABP5P2, ALG11, UTP14C, NEK5, AL139082.1, NEK3, MRPS31P5, AL158066.1, THSD1P1, AL158066.2, TPTE2P2, LINC02333, THSD1, RNY4P24, VPS36, AL359513.1, CKAP2, LINC00345, AL137058.1, AL137058.3, AL137058.2, MRPS31P4, HNRNPA1L2, SUGT1-DT, SUGT1, CNMD, MIR759, PPIAP26, PCDH8, OLFM4, LINC01065, AL136359.1, PCDH8P1, AL356295.1, RN7SL618P, AL450423.2, AL450423.1, ZNF646P1, LINC00558, LINC00458, AL356052.1, MIR1297, RPL13AP25, AL442636.1, AL512655.1, AL390964.1.
- chr14:87,996,345–88,881,078, 21 genes, copy number 10 (within-gene range 6–10): RNU6-835P, GPR65, AL157955.1, LINC01147, LINC01146, AL133279.2, AL133279.3, AL133279.1, KCNK10, SPATA7, PTPN21, AL162171.2, RNU4-22P, AL162171.1, ZC3H14, AL162171.3, EML5, AL121768.1, RNU4-92P, TTC8, Y_RNA.
- chr19:13,069,792–15,662,825, 119 genes, copy number 11 (broad region; genes not listed).
- chr19:20,746,923–21,125,270, 15 genes, copy number 9: AC010329.1, VN1R79P, ZNF66, BNIP3P24, AC008739.2, ZNF85, AC008739.6, KRT18P40, AC008739.1, ZNF430, AC008739.3, VN1R80P, ZNF714, RNA5SP469, VN1R81P.
- chr20:31,257,664–33,111,751, 78 genes, copy number 9–16 (broad region; genes not listed).
- chr20:36,605,779–36,951,843, 10 genes, copy number 10: RAB5IF, SLA2, HNRNPA3P2, NDRG3, Y_RNA, DSN1, SOGA1, RN7SL156P, TLDC2, SAMHD1.
- chr20:44,694,892–45,948,023, 74 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr22:37,125,843–37,807,436, 28 genes, copy number 11: IL2RB, Z82188.2, C1QTNF6, SSTR3, Z82188.1, RAC2, CYTH4, ELFN2, Z94160.1, ELFN2, Z94160.2, MFNG, CARD10, AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP, GGA1, SH3BP1, Z83844.2, PDXP-DT, PDXP, RN7SL385P, LGALS1, NOL12, Z83844.1, TRIOBP, H1-0.
- chr22:40,346,500–40,682,814, 12 genes, copy number 9: ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37, MCHR1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
